FM case AD15565 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/ac9dba0a-c957-4393-8d74-bf5ffe4ec3cc

Female, 34.5 years: Meningioma, NOS (ICD-O-3 9530/0) of the nervous system; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 83% (pathologist estimate recorded by GDC). Sample type: Metastatic.
